Somatic mutation profile of tumor specimen TARGET-40-0A4HX8-01A (aliquot TARGET-40-0A4HX8-01A-01D) from TARGET case TARGET-40-0A4HX8, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 29.1 years (10,635 days).
Specimen TARGET-40-0A4HX8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4317085-8ec6-4ae3-9f94-e9f2b1dff3fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4HX8-10A (Blood Derived Normal), aliquot TARGET-40-0A4HX8-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/987bf132-141e-4999-9871-91da0fc39d80

The open-access MAF lists 126 somatic variants for this specimen: 77 protein-altering or splice-affecting, 19 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 19, Intron 13, Nonsense Mutation 6, RNA 6, 3'UTR 5, Frame Shift Del 4, 5'UTR 4, Splice Site 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 72/80 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARV1 | c.518dup p.P174Afs*14 | Frame Shift Ins (INS) | VAF 20/38 reads (53%) | catalogued as rs544784472; called by mutect2, varscan2
- C2orf16 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs748621531, COSV68645327, COSV68645593; called by muse, mutect2, varscan2
- CSMD2 | c.6767T>C p.M2256T | Missense Mutation (SNP) | VAF 74/522 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53875268; called by muse, mutect2, varscan2
- CSMD3 | c.2665C>A p.P889T (on ENST00000297405 / NM_001363185.1; = p.P785T on NM_052900.3) | Missense Mutation (SNP) | VAF 30/347 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52293006; called by muse, mutect2
- DEPDC5 | c.1453C>G p.R485G | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV56707538; called by muse, mutect2, varscan2
- DMD | c.7295C>G p.T2432S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV58888696; called by muse, mutect2, varscan2
- DNM1L | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV56773602; called by muse, mutect2, varscan2
- FCRL2 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs978335006; called by muse, mutect2, varscan2
- FGGY | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs201320585; called by muse, mutect2, varscan2
- GSTA3 | c.645A>C p.E215D | Missense Mutation (SNP) | VAF 139/211 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760173301; called by muse, mutect2, varscan2
- KIF13A | c.1786+2T>G p.X596_splice | Splice Site (SNP) | VAF 595/799 reads (74%) | catalogued as rs1234375999; called by muse, mutect2, varscan2
- LUC7L2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1488540956, COSV54928619; called by muse, mutect2, varscan2
- MCTP1 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV56536630; called by muse, mutect2, varscan2
- NTS | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 152/279 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55455913; called by muse, mutect2, varscan2
- PTGER3 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.268); catalogued as rs1292607831, COSV60687833; called by muse, mutect2, varscan2
- RECQL | c.1160T>A p.I387N | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178901516; called by muse, mutect2, varscan2
- ROR2 | c.2183G>A p.C728Y | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65223845; called by muse, mutect2, varscan2
- RP1L1 | c.3011G>T p.G1004V | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV101223292; called by muse, mutect2, varscan2
- SKAP2 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs200204065; called by muse, mutect2, varscan2
- SLC34A2 | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 285/797 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs749325501; called by muse, mutect2, varscan2
- TEDC2 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs34948268; called by muse, varscan2
- TIAM1 | c.3882C>G p.F1294L | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs567504389, COSV54577078; called by muse, mutect2, varscan2
- VPS37D | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs372273560, COSV100265277; called by muse, mutect2
- ZNF184 | c.2180G>C p.G727A | Missense Mutation (SNP) | VAF 97/589 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV53005367; called by muse, mutect2, varscan2
- AAAS | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ABCC9 | c.1471A>G p.R491G | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- AC008397.2 | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 194/268 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ACACB | c.6493A>T p.K2165* | Nonsense Mutation (SNP) | VAF 182/599 reads (30%) | called by muse, mutect2, varscan2
- AFG1L | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ARHGEF12 | c.4112A>G p.E1371G | Missense Mutation (SNP) | VAF 45/477 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ASTL | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BACH2 | c.2350A>C p.S784R | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CCM2L | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 43/238 reads (18%) | called by muse, mutect2, varscan2
- CENPO | c.324T>A p.Y108* | Nonsense Mutation (SNP) | VAF 40/213 reads (19%) | called by muse, mutect2, varscan2
- CLRN3 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COCH | c.1361_1362del p.F454Cfs*9 (on ENST00000216361 / NM_001347720.1; = p.F389Cfs*9 on NM_004086.3) | Frame Shift Del (DEL) | VAF 24/238 reads (10%) | called by mutect2, pindel, varscan2
- COL20A1 | c.2561A>G p.K854R | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.123); called by muse, mutect2
- DENND3 | c.1318A>T p.N440Y | Missense Mutation (SNP) | VAF 88/970 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2
- DNAH8 | c.4871A>G p.D1624G | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.309); called by muse, mutect2
- EPHA7 | c.38T>G p.L13* | Nonsense Mutation (SNP) | VAF 50/158 reads (32%) | called by muse, mutect2, varscan2
- ESYT3 | c.403A>T p.I135F | Missense Mutation (SNP) | VAF 454/495 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FAT1 | c.13112T>C p.F4371S | Missense Mutation (SNP) | VAF 216/907 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FECH | c.548A>G p.E183G | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FERMT2 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GRXCR1 | c.264T>A p.S88R | Missense Mutation (SNP) | VAF 280/565 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECTD4 | c.5930T>A p.F1977Y | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HTT | c.5719-1G>C p.X1907_splice | Splice Site (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2, varscan2
- ITSN2 | c.1799A>G p.D600G | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KANSL1 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 54/447 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- KCNJ15 | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ15 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 162/177 reads (92%) | called by muse, mutect2, varscan2
- KIF14 | c.2940A>G p.I980M | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- KIF20B | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIFC1 | c.1709A>C p.E570A | Missense Mutation (SNP) | VAF 59/468 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC37A3 | c.3695A>C p.Y1232S | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.969); called by muse, mutect2
- LRRIQ1 | c.3015T>A p.D1005E | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPD6B | c.214T>C p.Y72H (on ENST00000409029 / NM_001317004.1; = p.Y96H on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM3 | c.2016G>T p.K672N (on ENST00000229854 / NM_001366374.2; = p.K662N on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MTMR11 | c.991T>G p.S331A (on ENST00000439741 / NM_001145862.2; = p.S259A on NM_181873.3) | Missense Mutation (SNP) | VAF 54/467 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH15 | c.2384A>C p.K795T | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NR5A1 | c.757A>T p.K253* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- PABPC1L | c.1200T>A p.F400L | Missense Mutation (SNP) | VAF 64/642 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIGT | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- POLR2A | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- PTPRZ1 | c.2971T>C p.S991P | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- RPRD2 | c.3094A>G p.K1032E | Missense Mutation (SNP) | VAF 363/935 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SERTAD4 | c.612_615del p.V206Mfs*42 | Frame Shift Del (DEL) | VAF 291/564 reads (52%) | called by mutect2, pindel, varscan2
- SETD2 | c.1651A>C p.S551R | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SH2D3A | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 103/483 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- TCHP | c.826_827del p.H276Sfs*3 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | called by mutect2, pindel, varscan2
- TMEM63C | c.977A>T p.D326V | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TPRG1L | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- WDR7 | c.2077T>C p.F693L | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- WDR81 | c.4403T>C p.V1468A (on ENST00000409644 / NM_001163809.2; = p.V417A on NM_152348.4) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by mutect2, varscan2
- ZAN | c.7032_7067delinsG p.F2345Sfs*10 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by pindel, varscan2*
- ACKR2 | c.198T>A p.L66= | Silent (SNP) | VAF 177/208 reads (85%) | called by muse, mutect2, varscan2
- ACTR8 | c.681A>G p.L227= | Silent (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- AHCY | c.513G>A p.G171= | Silent (SNP) | VAF 117/682 reads (17%) | catalogued as rs1187032251; called by muse, mutect2, varscan2
- BAG6 | c.1080C>T p.T360= | Silent (SNP) | VAF 26/428 reads (6%) | called by muse, mutect2
- CD244 | c.282C>T p.I94= | Silent (SNP) | VAF 42/264 reads (16%) | called by muse, mutect2, varscan2
- CEP170 | c.1101G>A p.R367= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs1443312372; called by muse, mutect2, varscan2
- DGKI | c.405A>G p.K135= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs1215535308; called by muse, mutect2, varscan2
- DYNC1I2 | c.1698T>C p.S566= | Silent (SNP) | VAF 95/598 reads (16%) | called by muse, mutect2, varscan2
- EDC3 | c.1426T>C p.L476= | Silent (SNP) | VAF 38/268 reads (14%) | called by muse, mutect2, varscan2
- ETFRF1 | c.27A>T p.G9= | Silent (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.273T>C p.F91= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- PCDHB15 | c.747G>A p.V249= | Silent (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- PPAT | c.297A>G p.K99= | Silent (SNP) | VAF 95/209 reads (45%) | called by muse, mutect2, varscan2
- PRKCQ | c.555A>G p.K185= | Silent (SNP) | VAF 41/193 reads (21%) | catalogued as COSV54111514; called by muse, mutect2, varscan2
- SCARF2 | c.993T>C p.C331= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- SLC7A8 | c.1488C>T p.P496= | Silent (SNP) | VAF 94/318 reads (30%) | catalogued as rs756620184; called by muse, mutect2, varscan2
- TET2 | c.2232G>A p.Q744= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- TNK2 | c.1338G>A p.V446= | Silent (SNP) | VAF 111/218 reads (51%) | catalogued as rs893956009; called by muse, mutect2, varscan2
- ZNF765 | c.1305G>A p.E435= | Silent (SNP) | VAF 74/334 reads (22%) | called by muse, mutect2, varscan2
- ALG1 | c.390+39T>C | Intron (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- ANAPC1P4 | n.262G>T | RNA (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- DDX18 | c.1066+145G>C | Intron (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2
- DDX20 | c.1210+19G>C | Intron (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- DMTN | c.*25C>T | 3'UTR (SNP) | VAF 14/132 reads (11%) | called by mutect2, varscan2
- ELF2P4 | n.195A>C | RNA (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- ETFB | c.58-91C>A | Intron (SNP) | VAF 52/214 reads (24%) | called by muse, mutect2, varscan2
- GNRHR2P1 | n.7G>C | RNA (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- GTF3C5 | c.572+102C>A | Intron (SNP) | VAF 43/52 reads (83%) | called by muse, mutect2, varscan2
- HELB | c.-57T>A | 5'UTR (SNP) | VAF 116/189 reads (61%) | called by muse, mutect2, varscan2
- ITGA2B | c.2943+82G>C | Intron (SNP) | VAF 85/226 reads (38%) | called by muse, mutect2, varscan2
- LAT | c.246-14C>T | Intron (SNP) | VAF 64/222 reads (29%) | catalogued as rs1349101705; called by muse, mutect2, varscan2
- LRRC37A | c.2906+4932G>C | Intron (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2, varscan2
- MAK16 | c.241-34C>A | Intron (SNP) | VAF 32/242 reads (13%) | called by muse, mutect2, varscan2
- NDOR1 | c.311+96C>T | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- OR10AG1 | c.*38G>A | 3'UTR (SNP) | VAF 22/42 reads (52%) | catalogued as rs1431299817; called by mutect2, varscan2
- PAG1 | c.*5501T>C | 3'UTR (SNP) | VAF 41/132 reads (31%) | called by muse, mutect2, varscan2
- PRLHR | c.-6-62G>C | Intron (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2
- PSMC2 | chr7:103344450 G>T | 5'Flank (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2
- PSMC2 | chr7:103344451 G>T | 5'Flank (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2
- RAET1E | c.*24G>A | 3'UTR (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- SFI1 | c.-10A>G | 5'UTR (SNP) | VAF 51/60 reads (85%) | called by muse, mutect2, varscan2
- SGK1 | c.1128+69G>C | Intron (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- SHQ1 | c.-44G>C | 5'UTR (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- SLC22A17 | n.826T>A | RNA (SNP) | VAF 52/160 reads (33%) | called by muse, mutect2, varscan2
- SPATA19 | c.-56C>G | 5'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- SYNE1 | c.9324+76T>C | Intron (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2
- TRIM51HP | n.840G>A | RNA (SNP) | VAF 151/361 reads (42%) | called by muse, mutect2, varscan2
- TUBB7P | n.379T>C | RNA (SNP) | VAF 128/338 reads (38%) | called by muse, varscan2
- USP46 | c.*129G>C | 3'UTR (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
